Gene-level copy-number profile of specimen HCM-CSHL-0728-C25-85A from HCMI case HCM-CSHL-0728-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 54.8 years (20,008 days).
Specimen HCM-CSHL-0728-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 220be4a2-72f9-4498-92d5-38964049b7f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0728-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/3b59a335-a599-4097-a5eb-e5f8a44ca8fc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,008; copy number 2: 42,546; copy number 3: 3,222; copy number 4: 73; copy number 5: 66.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 66 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:53,632,726–53,985,519, 17 genes, copy number 5 (within-gene range 4–5): ATP5MC2, AC073594.1, CALCOCO1, AC076968.2, CISTR, AC076968.1, RN7SKP289, HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3.
- chr12:55,009,746–55,427,192, 23 genes, copy number 5: AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76.
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 10,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
